Gene-level copy-number profile of tumor specimen TCGA-P3-A5QA-01A from TCGA case TCGA-P3-A5QA, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 41.4 years (15,125 days).
Specimen TCGA-P3-A5QA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.934a32b2-53d8-45b9-9701-061ace822549.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-P3-A5QA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/62527c7e-8bc5-46b4-b823-44f36d46b07b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 424; copy number 2: 11,864; copy number 3: 14,397; copy number 4: 27,563; copy number 5: 1,501; copy number 6: 1,718; copy number 7: 1,479; copy number 9: 710; copy number 11: 10; copy number 12: 56; copy number 13: 35; copy number 17: 33; copy number 25: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-P3-A5QA-01A-11D-A28Q-01): tumor purity 0.43, ploidy 2.91, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:9,442,060–9,442,380, 1 gene: RN7SL5P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 867 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 9 (broad region; genes not listed).
- chr8:48,193,850–54,871,720, 91 genes, copy number 13–25 (within-gene range 7–25) (broad region; genes not listed).
- chr9:131,576,770–132,406,851, 9 genes, copy number 11: RAPGEF1, RN7SL328P, EIF4A1P3, AL160271.1, AL160271.2, MED27, NTNG2, SETX, TTF1.
- chr9:132,421,641–132,421,690, 1 gene, copy number 11: RNU5D-2P.
- chr11:101,129,077–103,895,271, 56 genes, copy number 12 (within-gene range 2–12): PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1, AP002989.1, MIR4693.

Autosomal genes at a single copy (total copy number 1): 424. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
